Somatic mutation profile of tumor specimen TARGET-30-PALETP-01A (aliquot TARGET-30-PALETP-01A-01W) from TARGET case TARGET-30-PALETP, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 4.0 years (1,466 days).
Specimen TARGET-30-PALETP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95cd1d76-7be1-4101-ba13-15fd5f2c0afe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALETP-10A (Blood Derived Normal), aliquot TARGET-30-PALETP-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2eec810-2472-4edc-a70d-460fa3967725

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEFB121 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV66236349; called by muse, mutect2, varscan2
- FCRL5 | c.2204C>A p.A735D | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100708896, COSV62515082; called by muse, mutect2, varscan2
- FRYL | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV51948737; called by muse, mutect2, varscan2
- MADD | c.1443T>A p.D481E | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV60624756; called by muse, mutect2, varscan2
- SHANK2 | c.4195G>A p.V1399M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs544429954, COSV53602923; ClinVar: uncertain significance; called by muse, mutect2
- TAFA4 | c.47C>G p.S16W | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55138441; called by muse, mutect2, varscan2
- TENM1 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 316/2321 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV64433096; called by muse, mutect2, varscan2
- DNAJC16 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- DNAJC16 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LPA | c.3921G>C p.Q1307H | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); called by muse, mutect2
- VAMP5 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NOX5 | c.402C>A p.L134= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs768058504; called by muse, mutect2, varscan2
- OR1I1 | c.36C>T p.F12= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV52917913; called by muse, mutect2, varscan2
